CCDI case PBCFND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7835fede-23a7-4617-bd32-fb1940de8b43

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,100 days).

Biospecimens (3 samples)
- Sample 0DQU4F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQU4X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQU5E: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
